TARGET case TARGET-30-PAUKRF — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Retroperitoneum and peritoneum. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/50a1527f-30d6-5d2f-b17b-e8fab307bfa1

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 2 years; Vital status: Alive.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C48.8; Tissue or organ of origin: Overlapping lesion of retroperitoneum and peritoneum; Classification of tumor: primary; Age at diagnosis: 2.1 years (759 days); Year of diagnosis: 2011; Days to last follow up: 2,452 days (6.7 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4; Mitosis karyorrhexis index: High.
   Pathology details: Percent tumor nuclei: 90.
   Treatment given: Protocol identifier: ANBL00B1.
   Treatment given: Protocol identifier: ANBL0032.
   Treatment given: Protocol identifier: ANBL0532.

Follow-up (1 entry)
- Days to follow up: 2,452 days (6.7 years); Event-free: no event (relapse, second malignancy or death) recorded through day 2,452; Year of follow up: 2018.

Molecular and laboratory tests
- MYCN amplification: Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PAUKRF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PAUKRF-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Validation_20230322.xlsx (sheet Clinical Data):
- First Event: Censored
- Overall Survival Time in Days: 2452
- Protocol: ANBL00B1, ANBL0532, ANBL0032
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.88
- Histology: Unfavorable
- ICDO Description: Overlapping lesion of Re+V428troperitoneum and peritoneum
